Somatic mutation profile of tumor specimen C3N-01815-01 (aliquot CPT0167970006) from CPTAC case C3N-01815, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.1 years (25,973 days).
Specimen C3N-01815-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cfe46da-2a0b-4166-ac0a-c13114429270.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01815-71 (Blood Derived Normal), aliquot CPT0168030004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b53efd5b-4e10-4446-860b-8769ce21df45

The open-access MAF lists 62 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 12, Nonsense Mutation 4, Intron 2, 3'UTR 2, In Frame Del 2, Frame Shift Del 1, Splice Site 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 91/301 reads (30%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ALOX15 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 26/152 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.882); catalogued as rs764290738; called by muse, mutect2, varscan2
- ARAF | c.856G>C p.D286H | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV51691242; called by muse, mutect2, varscan2
- ARSF | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV63839756; called by muse, mutect2, varscan2
- CELSR1 | c.6686G>A p.R2229H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as rs745830567; called by muse, mutect2, varscan2
- CLCN2 | c.1612G>A p.V538I | Missense Mutation (SNP) | VAF 91/359 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1389726486, COSV55600186; called by muse, mutect2, varscan2
- DOCK10 | c.4655C>T p.A1552V | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.049); catalogued as rs775514083; called by muse, mutect2
- EFCAB3 | c.1062G>A p.W354* | Nonsense Mutation (SNP) | VAF 51/168 reads (30%) | catalogued as rs772156564; called by muse, mutect2, varscan2
- FAM83H | c.2185G>A p.A729T | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs782097582; called by muse, mutect2, varscan2
- FZD4 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs768413379; called by muse, mutect2, varscan2
- JPH2 | c.1936A>T p.T646S | Missense Mutation (SNP) | VAF 48/434 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs747762930; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MIDN | c.234-3C>T | Splice Region (SNP) | VAF 15/137 reads (11%) | catalogued as rs747251246, COSV99960252; called by muse, mutect2, varscan2
- MRGPRE | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200110994, COSV101099986; called by muse, mutect2, varscan2
- NID2 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.08); catalogued as rs749092514; called by muse, mutect2, varscan2
- NPAS2 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs764579373, COSV59561480; called by muse, mutect2, varscan2
- OBSCN | c.21701C>T p.S7234L | Missense Mutation (SNP) | VAF 101/478 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs776508320; called by muse, mutect2, varscan2
- PAXBP1 | c.2035A>G p.I679V | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.726); catalogued as rs768854048; called by muse, mutect2, varscan2
- PCDHA2 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 75/602 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.713); catalogued as COSV65370441; called by muse, mutect2, varscan2
- PDZD9 | c.335_337del p.I112del (on ENST00000424898 / NM_001363519.1; = p.I52del on NM_173806.4) | In Frame Del (DEL) | VAF 38/170 reads (22%) | catalogued as rs1377450898; called by pindel, varscan2
- RAB11FIP3 | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.192); catalogued as rs551916328; called by muse, mutect2, varscan2
- RYR1 | c.4759G>A p.A1587T | Missense Mutation (SNP) | VAF 122/493 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as rs1030955858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SETMAR | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.024); catalogued as rs968658005, COSV100740917; called by muse, mutect2, varscan2
- TNRC6B | c.4766A>G p.H1589R (on ENST00000454349 / NM_001162501.2; = p.H1479R on NM_015088.3) | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.942); catalogued as rs887741530; called by muse, mutect2, varscan2
- TRAP1 | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs754378125, COSV55917501; called by muse, mutect2, varscan2
- UPF3B | c.70G>A p.G24S | Missense Mutation (SNP) | VAF 91/420 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs961446418; called by muse, mutect2, varscan2
- ADGRE1 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ANKIB1 | c.1600C>T p.H534Y | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP7A | c.3785G>C p.R1262T | Missense Mutation (SNP) | VAF 18/476 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.379); called by muse, mutect2
- CSN1S1 | c.148A>C p.N50H | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DENND2A | c.2110G>T p.E704* | Nonsense Mutation (SNP) | VAF 25/197 reads (13%) | called by muse, mutect2, varscan2
- EYS | c.5255T>A p.I1752N | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXL17 | c.1328T>C p.V443A | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- HAUS7 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 48/286 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LYPD3 | c.1035_1037del p.L346del | In Frame Del (DEL) | VAF 6/52 reads (12%) | called by mutect2, pindel
- MAML1 | c.219G>C p.K73N | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- MAMSTR | c.1040T>G p.L347R (on ENST00000318083 / NM_001130915.2; = p.L244R on NM_182574.2) | Missense Mutation (SNP) | VAF 32/181 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- MBTPS2 | c.54C>G p.Y18* | Nonsense Mutation (SNP) | VAF 97/581 reads (17%) | called by muse, varscan2
- MYH10 | c.1213C>T p.R405* | Nonsense Mutation (SNP) | VAF 37/152 reads (24%) | called by muse, mutect2, varscan2
- NLGN3 | c.2117C>G p.T706S (on ENST00000358741 / NM_181303.2; = p.T686S on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- NR3C2 | c.2795A>G p.H932R | Missense Mutation (SNP) | VAF 24/350 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); called by muse, mutect2
- PLA2G4F | c.1490C>A p.T497N | Missense Mutation (SNP) | VAF 51/306 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- RNPC3 | c.698del p.P233Qfs*25 | Frame Shift Del (DEL) | VAF 30/231 reads (13%) | called by mutect2, pindel, varscan2
- SGO1 | c.895A>G p.N299D | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRPC6 | c.2009+1G>T p.X670_splice | Splice Site (SNP) | VAF 32/157 reads (20%) | called by muse, mutect2, varscan2
- TTN | c.50278G>A p.V16760I (on ENST00000591111; = p.V9336I on NM_003319.4) | Missense Mutation (SNP) | VAF 71/173 reads (41%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY2 | c.1912T>C p.L638= | Silent (SNP) | VAF 32/319 reads (10%) | catalogued as rs764534798; called by muse, mutect2
- CLIC4 | c.330A>G p.K110= | Silent (SNP) | VAF 30/145 reads (21%) | called by muse, mutect2, varscan2
- IL2RA | c.39C>T p.F13= | Silent (SNP) | VAF 38/145 reads (26%) | catalogued as COSV56921086; called by muse, mutect2, varscan2
- LCE2D | c.291T>C p.S97= | Silent (SNP) | VAF 28/122 reads (23%) | catalogued as COSV64228873, COSV64229238; called by mutect2, varscan2
- MXRA5 | c.6402G>A p.T2134= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV54236594; called by muse, mutect2, varscan2
- NAP1L4 | c.450G>A p.T150= | Silent (SNP) | VAF 46/222 reads (21%) | catalogued as rs766744653; called by muse, mutect2, varscan2
- PSD4 | c.246C>T p.D82= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs147089589; called by muse, mutect2, varscan2
- RBM27 | c.783C>T p.N261= | Silent (SNP) | VAF 59/278 reads (21%) | called by muse, mutect2, varscan2
- TMEM243 | c.121T>C p.L41= | Silent (SNP) | VAF 33/220 reads (15%) | catalogued as rs756720367; called by muse, mutect2, varscan2
- TOR4A | c.1023C>T p.R341= | Silent (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- UNC45B | c.1392A>G p.S464= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as rs749591189; called by muse, varscan2
- VPS33B | c.687T>C p.F229= | Silent (SNP) | VAF 79/373 reads (21%) | called by muse, mutect2, varscan2
- ARL13B | c.*444T>A | 3'UTR (SNP) | VAF 8/43 reads (19%) | called by muse, mutect2
- MPP1 | c.102+5493A>G | Intron (SNP) | VAF 12/112 reads (11%) | called by muse, mutect2
- RGL3 | c.-35_-32del | 5'UTR (DEL) | VAF 16/86 reads (19%) | called by pindel, varscan2
- TAFA4 | c.*44C>T | 3'UTR (SNP) | VAF 18/98 reads (18%) | catalogued as rs749618496, COSV99806708; called by muse, mutect2, varscan2
- TTLL10 | c.-28+1565C>T | Intron (SNP) | VAF 134/658 reads (20%) | catalogued as rs562023142; called by muse, varscan2
